Surgical pathology report (de-identified scan), TCGA case TCGA-QR-A707, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site National Institutes of Health, specimen TCGA-QR-A707-01A (Primary Tumor).

[page 1 of 2]
Final Results

Surgical Pathology [OrderID:]

Final

Surgical Pathology

CASE NUMBER

DIAGNOSIS: Adrenal gland, left, tumor, resection: Pheochromocytoma, see note.

NOTE: Tumor cells are strongly positive for synaptophysin and chromogranin. Areas of intratumoral necro-hemorrhage and fibrosis are seen.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the . They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Allocate Order to Protocol:

Brief

Clinical History: Left

adrenal gland tumor, suspected pheo chromocytoma based on serum and

urine catecholamines Specimen Taken For Protocol: 01 - Yes

PROCEDURE: Pre-Operative Diagnosis: Left adrenal gland tumor, Post-Operative

Diagnosis: Left adrenal gland tumor, Operative Findings: Left adrenal gland tumor,

SPECIMENS SUBMITTED: 1. ADRENAL GLAND, LEFT

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and further specified as "left adrenal". The specimen consists of an adrenal gland weighing 164.7 grams, measuring overall 8.6 x 7.5 x 5.0 cm. There is a small defect on the surface measuring 3 cm. The specimen is inked in black. The specimen is opened on the opposite of defect to reveal a hollow mass with friable tissue in the middle. The cut surface has an outer rim of adrenal gland, beneath which is a tan-pink smooth tissue. Up to 4 x 3 x 2 cm of the firm pink-tan tissue is procured for and Lab. In Surgical Pathology, the specimen received matches the above description. Small sections are made to open the mass and fix overnight. Representative sections are made and submitted in white cassettes labeled for permanent processing. The procurement was performed by Additional sections from the tumor are made, and they are submitted in white cassettes labeled for permanent processing.

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Do not file in Medical Record

Requested By:

ICD-0-3
Pheochromocytoma NOS
Site Adrenal gland NOS
C74.9

8/8/13

[page 2 of 2]
Surgical Pathology	Final Results
---------------------------	----------------------

Gross description dictated by

No consultants

#

#

	Yes	No
Unilateral/Synchronous Primary		✓

Confidential Patient Information. Unauthorized disclosure is prohibited by the Federal Privacy Act of 1974.

Do not file in Medical Record

Requested By:

Source: NCI Genomic Data Commons file 9af29f5a-6916-4685-857f-a5c60ab0e557 (TCGA-QR-A707.6789B885-26AB-4F99-9C3D-6B4DBA2FA05B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).